Somatic mutation profile of tumor specimen MMRF_1676_1_BM_CD138pos (aliquot MMRF_1676_1_BM_CD138pos_T2_KBS5U_L05373) from MMRF case MMRF_1676, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.1 years (18,666 days).
Specimen MMRF_1676_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b86210e-46fd-4236-bb11-53a060586a3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1676_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1676_1_PB_Whole_C3_KBS5U_L05535; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56af0b44-5471-4d3e-b319-dd8a281c9d25

The open-access MAF lists 198 somatic variants for this specimen: 80 protein-altering or splice-affecting, 25 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, 3'UTR 32, Silent 25, 5'UTR 21, Intron 18, 5'Flank 14, Nonsense Mutation 4, 3'Flank 4, RNA 4, Splice Site 3, Frame Shift Del 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 34/109 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACHE | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as rs1483126679; called by muse, mutect2, varscan2
- ADAMTS2 | c.3013G>A p.A1005T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs757793067, COSV52371239; called by muse, mutect2, varscan2
- BFSP1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as rs745724447, COSV64900058; called by muse, mutect2, varscan2
- CER1 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1197693840; called by muse, mutect2
- CNTN4 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.097); catalogued as rs780874348, COSV68583535; called by muse, mutect2, varscan2
- CNTNAP3 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1322493756; called by muse, mutect2
- GPR107 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs1193233653; called by muse, mutect2, varscan2
- GREM1 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 103/198 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55714732; called by muse, mutect2, varscan2
- HAO2 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776787457; called by muse, mutect2, varscan2
- IGHV2-70 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs567922038; called by muse, varscan2
- IGLL5 | c.206+1G>C p.X69_splice | Splice Site (SNP) | VAF 13/24 reads (54%) | catalogued as rs769556163, COSV73249537, COSV73250119, COSV73251144; called by muse, mutect2, varscan2
- IGLV3-1 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs369981261; called by muse, varscan2
- IGLV3-1 | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs561290535; called by muse, varscan2
- JKAMP | c.853G>A p.V285M (on ENST00000554271 / NM_001284201.1; = p.V271M on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1000515146; called by muse, mutect2, varscan2
- KIF26A | c.1913G>A p.C638Y | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778867803; called by muse, mutect2, varscan2
- KRTCAP3 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.213); catalogued as rs770393187; called by muse, mutect2, varscan2
- MYH7B | c.5210G>C p.R1737P | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52683053; called by muse, mutect2, varscan2
- MYO15A | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs777015124; called by muse, mutect2, varscan2
- NCAM1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1427701599, COSV57511562; called by muse, mutect2, varscan2
- NEURL1 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63915285; called by muse, mutect2, varscan2
- OLFM3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV58796053; called by muse, mutect2, varscan2
- PCDHA4 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs782455641, COSV63543263; called by muse, mutect2, varscan2
- PDSS2 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1217767868, COSV100941870; called by muse, mutect2, varscan2
- PLK1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs754746085; called by muse, mutect2, varscan2
- RIPOR2 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52419758; called by muse, mutect2, varscan2
- SETD2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as COSV57443300; called by muse, mutect2, varscan2
- SGPP1 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766517011; called by muse, mutect2, varscan2
- SLC16A7 | c.1265T>A p.L422H | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs1479264088; called by muse, mutect2, varscan2
- SLC27A1 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs140567146; called by muse, mutect2, varscan2
- SLC29A2 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1433003361; called by muse, mutect2, varscan2
- SP9 | c.1401_1409del p.A468_A470del | In Frame Del (DEL) | VAF 36/86 reads (42%) | catalogued as rs746223726; called by mutect2, varscan2
- ST8SIA5 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | PolyPhen possibly damaging (0.531); catalogued as COSV100164805, COSV59335309; called by muse, mutect2, varscan2
- TLX3 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs773035137; called by muse, mutect2, varscan2
- TMEM250 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs778197885; called by muse, mutect2, varscan2
- TXNRD2 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs749423408; called by muse, mutect2, varscan2
- VENTX | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs45485699, COSV58084624; called by muse, mutect2, varscan2
- VHL | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56550884; called by muse, mutect2
- ZNF407 | c.3679C>T p.R1227C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as rs369946815; called by muse, mutect2, varscan2
- CETN1 | c.519A>G p.*173Wext*6 | Nonstop Mutation (SNP) | VAF 114/234 reads (49%) | called by muse, mutect2, varscan2
- COL5A3 | c.2710C>G p.L904V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- CRAT | c.1642C>A p.H548N | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CYP3A5 | c.1026+4A>C | Splice Region (SNP) | VAF 43/51 reads (84%) | called by muse, mutect2, varscan2
- ENPP2 | c.1880T>C p.L627P (on ENST00000075322 / NM_001040092.3; = p.L679P on NM_006209.5) | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- FAT1 | c.3905T>G p.I1302S | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.9415T>C p.F3139L | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FOXI1 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 107/177 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FRMD7 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCC2 | c.2864A>C p.N955T | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- GFPT2 | c.214+7G>A | Splice Region (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- GJD3 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID2IP | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGH1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IFT74 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.295T>A p.Y99N | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- IGHV2-70D | c.47-2A>T p.X16_splice | Splice Site (SNP) | VAF 27/35 reads (77%) | called by muse, varscan2
- IGLV3-1 | c.255_279del p.G86Afs*? | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by pindel, varscan2
- ITGB2 | c.2342C>T p.A781V (on ENST00000302347; = p.A757V on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF7 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL11 | c.444del p.E150Nfs*8 | Frame Shift Del (DEL) | VAF 32/102 reads (31%) | called by mutect2, pindel, varscan2
- MYMK | c.68G>C p.S23T | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- NCKAP5 | c.2394A>T p.Q798H | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.562); called by muse, mutect2
- OLFM1 | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- OLFM1 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- PCDH8 | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RSL1D1 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SDF2 | c.48_50del p.G17del | In Frame Del (DEL) | VAF 72/169 reads (43%) | called by mutect2, pindel, varscan2
- SHANK3 | c.4916C>T p.A1639V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK4 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SMARCAD1 | c.2846T>C p.I949T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ST6GAL2 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 24/56 reads (43%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBXT | c.427T>C p.F143L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEFM | c.19T>C p.F7L | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- TMEM229A | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TRIP12 | c.2982-2A>G p.X994_splice | Splice Site (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- UBE2O | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, varscan2
- UBE2O | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.039); called by muse, varscan2
- UPF1 | c.1272del p.F424Lfs*15 (on ENST00000599848 / NM_001297549.2; = p.F413Lfs*15 on NM_002911.4) | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- ZC3H7A | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZDHHC5 | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG3 | c.579C>A p.R193= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- ARID4B | c.1989G>A p.R663= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- ATP8B4 | c.780T>C p.G260= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs143449174; called by muse, mutect2, varscan2
- BRWD3 | c.675T>A p.I225= | Silent (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- CDH3 | c.2172C>T p.A724= | Silent (SNP) | VAF 56/59 reads (95%) | called by muse, mutect2, varscan2
- CYP2A13 | c.981C>A p.V327= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as COSV57838431; called by muse, mutect2, varscan2
- EGFL8 | c.138G>A p.P46= | Silent (SNP) | VAF 88/145 reads (61%) | catalogued as rs575900965; called by muse, mutect2, varscan2
- EPS8L3 | c.528C>T p.L176= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as rs753378857; called by muse, mutect2, varscan2
- GPR158 | c.2484G>A p.T828= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as rs1218891774, COSV100893006; called by muse, mutect2, varscan2
- GTF3A | c.181C>T p.L61= | Silent (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- HMCN2 | c.5394C>T p.A1798= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- IGLL5 | c.120C>G p.R40= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs755794558, COSV104440336, COSV73249987; called by muse, mutect2, varscan2
- IL19 | c.450C>T p.H150= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs778276774; called by muse, mutect2, varscan2
- LMAN2 | c.951C>T p.P317= | Silent (SNP) | VAF 48/130 reads (37%) | called by muse, mutect2, varscan2
- MTRF1L | c.304T>C p.L102= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- OPN4 | c.510G>T p.L170= | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- OR5P2 | c.267C>A p.S89= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100271442; called by muse, mutect2
- PCDH8 | c.2520T>C p.P840= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1434717255; called by muse, mutect2, varscan2
- PYCR1 | c.690C>T p.N230= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs761756388; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAS2R60 | c.759C>T p.A253= | Silent (SNP) | VAF 46/74 reads (62%) | called by muse, mutect2, varscan2
- THSD7A | c.831C>T p.R277= | Silent (SNP) | VAF 99/308 reads (32%) | catalogued as rs377308966, COSV70261643; called by muse, mutect2, varscan2
- TIAM2 | c.2385T>C p.Y795= | Silent (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- USP44 | c.381T>C p.D127= | Silent (SNP) | VAF 89/185 reads (48%) | catalogued as COSV51562119; called by muse, mutect2, varscan2
- WWC1 | c.822G>A p.P274= | Silent (SNP) | VAF 125/197 reads (63%) | catalogued as rs1356011702; called by muse, mutect2, varscan2
- ZFP42 | c.846C>T p.C282= | Silent (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- ADD2 | c.1593+954C>T | Intron (SNP) | VAF 37/69 reads (54%) | catalogued as rs1019439179; called by muse, mutect2, varscan2
- ADD3 | c.*537G>A | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- ADGRL4 | c.22+14G>A | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- AKAP6 | c.3588+53dup | Intron (INS) | VAF 77/170 reads (45%) | catalogued as rs1199052520; called by mutect2, pindel, varscan2
- ALG10 | chr12:34022318 T>C | 5'Flank (SNP) | VAF 61/128 reads (48%) | called by muse, mutect2, varscan2
- ANKRD28 | c.-361C>T | 5'UTR (SNP) | VAF 88/124 reads (71%) | called by muse, varscan2
- ANKRD40 | c.*2698A>G | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.*308C>T | 3'UTR (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- ARID4B | c.3448+982C>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- ATOX1 | c.*46+1653C>G | Intron (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021081 T>C | 5'Flank (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021351 T>G | 5'Flank (SNP) | VAF 44/86 reads (51%) | catalogued as COSV55852152; called by muse, varscan2
- BCL7A | chr12:122021359 T>G | 5'Flank (SNP) | VAF 42/88 reads (48%) | called by muse, varscan2
- BCL7A | chr12:122021382 T>C | 5'Flank (SNP) | VAF 42/91 reads (46%) | called by muse, varscan2
- BMPR2 | c.*2629A>G | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- BRF1 | c.*932C>A | 3'UTR (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- BRWD3 | c.*4980A>T | 3'UTR (SNP) | VAF 38/64 reads (59%) | called by muse, mutect2, varscan2
- C8orf86 | n.680G>A | RNA (SNP) | VAF 40/43 reads (93%) | called by muse, mutect2, varscan2
- C8orf86 | n.679G>A | RNA (SNP) | VAF 42/45 reads (93%) | catalogued as COSV100817580; called by muse, mutect2, varscan2
- CASC3 | c.*838T>C | 3'UTR (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- CD37 | c.-9T>C | 5'UTR (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- CELF2 | c.*1541T>A | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, varscan2
- CENPS-CORT | c.51+738G>A | Intron (SNP) | VAF 30/58 reads (52%) | catalogued as rs1188714645; called by muse, mutect2, varscan2
- CTSB | c.-25-96G>A | Intron (SNP) | VAF 11/12 reads (92%) | called by muse, mutect2, varscan2
- DHRS12 | c.844+265_844+306del | Intron (DEL) | VAF 40/90 reads (44%) | called by mutect2, pindel
- ENG | c.-243G>A | 5'UTR (SNP) | VAF 57/110 reads (52%) | called by muse, mutect2, varscan2
- ERCC5 | c.-98G>A | 5'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2
- ERCC5 | c.-97G>A | 5'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2
- ETV1 | chr7:13891700 T>A | 3'Flank (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- FADS2 | c.*602C>T | 3'UTR (SNP) | VAF 156/256 reads (61%) | called by muse, mutect2
- FBXL6 | c.417-31G>A | Intron (SNP) | VAF 38/49 reads (78%) | catalogued as rs1322178967; called by muse, mutect2, varscan2
- FOXI2 | c.*1581G>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, varscan2
- FYTTD1 | chr3:197749472 G>A | 5'Flank (SNP) | VAF 20/39 reads (51%) | catalogued as rs1204503529; called by muse, mutect2, varscan2
- FYTTD1 | chr3:197749473 G>A | 5'Flank (SNP) | VAF 22/41 reads (54%) | catalogued as COSV54084199; called by muse, mutect2, varscan2
- GPR19 | chr12:12661012 A>C | 3'Flank (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- HELLPAR | n.200280T>G | RNA (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- HGSNAT | c.*2447T>G | 3'UTR (SNP) | VAF 42/47 reads (89%) | called by muse, mutect2, varscan2
- HOXC5 | c.*633G>A | 3'UTR (SNP) | VAF 132/233 reads (57%) | called by muse, mutect2, varscan2
- HTR3A | c.265-17C>T | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as rs759559858; called by muse, mutect2
- IGSF3 | c.*1471G>A | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- ISX | c.*1266T>G | 3'UTR (SNP) | VAF 51/133 reads (38%) | called by muse, mutect2, varscan2
- ITK | c.*939G>C | 3'UTR (SNP) | VAF 66/101 reads (65%) | called by muse, mutect2
- KCNQ1 | c.*331G>A | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- KDSR | c.-36del | 5'UTR (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- KIAA1958 | c.*5029A>C | 3'UTR (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- KPNA6 | c.*1290G>A | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- KRT6A | c.*5C>T | 3'UTR (SNP) | VAF 30/57 reads (53%) | catalogued as rs746987648, COSV58107900; called by muse, mutect2, varscan2
- KRTAP24-1 | c.*301G>A | 3'UTR (SNP) | VAF 48/68 reads (71%) | catalogued as rs867315252; called by muse, mutect2, varscan2
- LMLN | c.*948T>C | 3'UTR (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- LTB | c.162+100G>A | Intron (SNP) | VAF 36/58 reads (62%) | called by muse, mutect2, varscan2
- MAGEA10 | c.*1069del | 3'UTR (DEL) | VAF 10/25 reads (40%) | catalogued as rs968990267; called by mutect2, pindel, varscan2
- MAP3K9 | chr14:70809196 G>A | 5'Flank (SNP) | VAF 10/19 reads (53%) | called by muse, varscan2
- MAP3K9 | chr14:70809197 G>A | 5'Flank (SNP) | VAF 10/18 reads (56%) | called by muse, varscan2
- MAPKAPK5 | chr12:111842084 G>A | 5'Flank (SNP) | VAF 16/23 reads (70%) | catalogued as rs1451305002; called by muse, mutect2, varscan2
- MARK3 | c.-90C>G | 5'UTR (SNP) | VAF 31/70 reads (44%) | called by muse, varscan2
- ME1 | c.*833T>G | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- MEIS1 | c.*1273del | 3'UTR (DEL) | VAF 13/33 reads (39%) | catalogued as rs976507976; called by mutect2, varscan2
- MIR5195 | chr14:106851366 G>A | 5'Flank (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- MYC | c.-154G>A | 5'UTR (SNP) | VAF 41/66 reads (62%) | catalogued as COSV104388525; called by muse, mutect2, varscan2
- MYO1E | c.-114A>C | 5'UTR (SNP) | VAF 63/130 reads (48%) | called by muse, mutect2, varscan2
- NCAM2 | c.-7C>A | 5'UTR (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- NCOR2 | c.3845-28C>T | Intron (SNP) | VAF 43/86 reads (50%) | catalogued as rs1257323114; called by muse, mutect2, varscan2
- NFIB | c.*6095dup | 3'UTR (INS) | VAF 33/68 reads (49%) | catalogued as rs1465946127; called by mutect2, varscan2
- NME3 | c.*97C>T | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- OPCML | c.-348C>T | 5'UTR (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110171647 C>T | 3'Flank (SNP) | VAF 89/191 reads (47%) | called by muse, mutect2
- PBLD | c.-11T>C | 5'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- PGM2 | c.-3G>T | 5'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- PIP5KL1 | c.595-25C>T | Intron (SNP) | VAF 96/185 reads (52%) | catalogued as rs778323835; called by muse, mutect2, varscan2
- PRRX1 | c.599+1029T>C | Intron (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- RASA1 | c.-164C>T | 5'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- RASSF4 | c.139-57del | Intron (DEL) | VAF 48/116 reads (41%) | called by mutect2, pindel, varscan2
- ROBO2 | c.-147G>A | 5'UTR (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- SASH3 | c.-15C>T | 5'UTR (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100795305; called by muse, mutect2, varscan2
- SCRN1 | c.*2727G>A | 3'UTR (SNP) | VAF 80/130 reads (62%) | catalogued as rs1044843023; called by muse, mutect2, varscan2
- SFT2D1 | c.-23C>T | 5'UTR (SNP) | VAF 58/138 reads (42%) | catalogued as rs757167666; called by muse, mutect2
- SLC1A1 | c.*209T>C | 3'UTR (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- SLC25A51P4 | n.443A>G | RNA (SNP) | VAF 67/198 reads (34%) | called by muse, mutect2, varscan2
- SLC27A2 | c.-16G>A | 5'UTR (SNP) | VAF 52/118 reads (44%) | catalogued as rs761414181; called by muse, mutect2, varscan2
- SLIT2 | c.179+957G>T | Intron (SNP) | VAF 6/130 reads (5%) | catalogued as rs1423423613; called by muse, mutect2
- SMAD2 | c.*8755T>C | 3'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- SYT4 | c.-182G>A | 5'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- TM7SF2 | c.304+88C>G | Intron (SNP) | VAF 25/35 reads (71%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975478 G>A | 5'Flank (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975647 C>T | 5'Flank (SNP) | VAF 76/139 reads (55%) | catalogued as COSV66081588; called by muse, mutect2, varscan2
- TSPAN15 | c.-103G>A | 5'UTR (SNP) | VAF 11/22 reads (50%) | catalogued as rs993926562; called by muse, mutect2, varscan2
- UNC5C | c.775+2350A>C | Intron (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- VN2R19P | chr19:58011036 G>A | 3'Flank (SNP) | VAF 76/112 reads (68%) | catalogued as rs1056679253; called by muse, mutect2, varscan2
- ZC3H6 | c.*1019G>A | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- ZDHHC12 | c.*53C>A | 3'UTR (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- ZNF135 | c.*180A>G | 3'UTR (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- ZNF341 | chr20:33731870 G>A | 5'Flank (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- ZNF862 | c.-158C>A | 5'UTR (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
